MMRF case MMRF_1596 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5e01a01d-860e-40ec-b0b3-227799f43f4b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Dead; Days to death: 382 days (1.0 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.2 years (24,542 days); ISS stage: II; Days to last known disease status: 382 days (1.0 years); Days to last follow up: 382 days (1.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 8 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 186 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 15 days; Days to treatment end: 186 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 200 days; Days to treatment end: 249 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Doxorubicin + Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 284 days; Days to treatment end: 310 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 327 days; Days to treatment end: 343 days.
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 327 days; Days to treatment end: 364 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 356 days; Days to treatment end: 364 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 382.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 4.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 98.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 57.1 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 3.61 µg/mL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.38 mmol/L; Albumin 35 g/L; Total Protein 10.9 g/dL; Glucose 5.06 mmol/L; C-Reactive Protein 1.9 mg/dL.
- Day 88 (ECOG 1): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 68.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.578 mg/dL; Immunoglobulin G 18.7 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 48 g/L; Total Protein 6.9 g/dL; Glucose 6.05 mmol/L.
- Day 186 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 20 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.729 mg/dL; Immunoglobulin G 15.5 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 5.89 mmol/L.
- Day 279 (ECOG 1): M Protein 2.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1916 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.188 mg/dL; Immunoglobulin G 44.8 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 4.1 µg/mL; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 12 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 35 g/L; Total Protein 9.4 g/dL; Glucose 6.66 mmol/L.
- Day 347 (ECOG 1): M Protein 2.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 139 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.193 mg/dL; Immunoglobulin G 35.5 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 3.5 µg/mL; Lactate Dehydrogenase 3.73 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 23 ×10⁹/L; Creatinine 212 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.73 mmol/L; Albumin 31 g/L; Total Protein 7.8 g/dL; Glucose 6.6 mmol/L.

Other clinical attributes
- Day 1: Weight: 79 kg; Height: 171 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (2 samples)
- Sample MMRF_1596_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1596_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
